Gene-level copy-number profile of tumor specimen HCM-CSHL-0174-C22-01A from HCMI case HCM-CSHL-0174-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 64.9 years (23,717 days).
Specimen HCM-CSHL-0174-C22-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a9060e4c-2541-410c-8443-804a129ae831.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0174-C22-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/f55ef376-bf8b-412f-b0ed-e425a7d3cc45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 11,135; copy number 2: 44,470; copy number 3: 2,756.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:36,169,767–37,861,802, 33 genes (within-gene range 0–1): RFC3P1, STAC, NBPF21P, RN7SKP227, DCLK3, HSPD1P6, LINC02033, AC105749.1, TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA, UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1, AC097359.1, AC097359.3, AC097359.2, GOLGA4, TCEA1P2, RNA5SP129, C3orf35, ITGA9, RNU7-73P, ITGA9-AS1, RPL21P135.
- chr3:42,145,646–42,146,371, 1 gene (within-gene range 0–1): TPMTP2.
- chr3:52,534,013–52,685,917, 4 genes (within-gene range 0–1): SMIM4, PBRM1, RNU6-856P, RNU6ATAC16P.
- chr7:149,069,641–149,090,782, 1 gene: ZNF786.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
